Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7100, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7100-01A (Primary Tumor).

[page 1 of 2]
**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. ****

SUPPLEMENTAL REPORT

DIAGNOSIS:

- (D) LEFT INFERIOR MARGIN OF LEFT MANDIBLE:
SQUAMOUS CARCINOMA INVADING BONE.
Margins of excision free of tumor.
- (F) HORIZONTAL AND ASCENDING RAMUS LEFT MANDIBLE:
Bone, no tumor.

This supplemental report is issued to report bone submitted for decalcification.

Entire report and diagnosis completed by: [REDACTED]

DIAGNOSIS

- (A) NODE OF LEFT LEVEL IIB:
METASTATIC SQUAMOUS CARCINOMA IN 1 OF 1 LYMPH NODE.
- (B) TISSUE OVERLYING LEVEL IIB NODE:
Fibroadipose tissue, no tumor.
- (C) MASS, LONG LEFT SIDE OF MANDIBLE:
INVASIVE POORLY DIFFERENTIATED SQUAMOUS CARCINOMA, TUMOR AT MARGIN
DESIGNATED ANTERIOR MEDIAL.
Other margins free.
- (D) LEFT INFERIOR MARGIN OF LEFT MANDIBLE:
Bone submitted for decalcification, supplemental report will follow.
- (E) TEETH:
Gross diagnosis only.
- (F) HORIZONTAL AND ASCENDING RAMUS LEFT MANDIBLE:
Bone, submitted for decalcification, supplemental report will follow.

Entire report and diagnosis completed by: [REDACTED]

[page 2 of 2]
GROSS DESCRIPTION

(A) NODE OF LEFT LEVEL IIB - A 2.3 x 1.5 x 1.3 cm lymph node corresponding to the upper posterior cervical/midjugular area (as per Dr. [REDACTED]).

SECTION CODE: A1-A3, lymph node in toto. [REDACTED]

(B) TISSUE OVERLYING LEVEL IIB NODE - An irregular piece of skeletal muscle and fat (3.5 x 1.9 x 0.8 cm) without discrete lesions.

SECTION CODE: B1-B3, entirely submitted. [REDACTED]

(C) MASS, LONG LEFT SIDE OF MANDIBLE - An irregular excision of soft tissue and skeletal muscle (5.8 x 4.3 x 2.3 cm) marked with a clamp on the anterior aspect. The specimen is further oriented by [REDACTED].

There is a well-circumscribed, nodular, tan-gray, fleshy mass (2.8 x 2.5 x 2.2 cm) which extends up to within 1.0 mm of the medial, 2.0 mm of the anterior, 3.0 mm of the superior, and 4.0 mm of the inferior and more than 1.0 cm of the lateral resection margins.

INKING CODE: Red-anterior (cheek); orange-posterior (mandible); yellow-medial (chin); black-lateral (ear); green-inferior; black-superior.

SECTION CODE: C1-C4, medial resection margin, perpendicular, in toto; C5, closest anterior margin; C6, closest superior margin; C7, closest deep margin; C8-C10, tumor. [REDACTED]

(D) LEFT INFERIOR MARGIN OF LEFT MANDIBLE - A 3.5 x 2.0 x 1.5 cm wedge resection of mandible with a roughened area (2.8 x 1.5 cm) on the external surface. The specimen is sent to the Bone Lab for decalcification and further sectioning. [REDACTED]

(E) TEETH - Three teeth (2.5-1.8 cm including two molars with porcelain crowns and a premolar with a resin). No sections taken. Gross examination only. [REDACTED]

(F) HORIZONTAL AND ASCENDING RAMUS LEFT MANDIBLE - A segmental mandibular resection (6.5 x 2.0 x 1.7 cm) without discrete lesions. The specimen is sent to the bone lab for decalcification and further sectioning. [REDACTED]

SNOMED CODES

M-80703 T-11180

Source: NCI Genomic Data Commons file 50371ea1-1976-4584-aad7-5910bd2cb96e (TCGA-CV-7100.1C84C32F-B2F9-4765-AF04-A853671CF245.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).